Somatic mutation profile of tumor specimen MBCProject_0099_T3_WES (aliquot MBCProject_0099_T3_WES_1) from CMI case MBCProject_0099, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.9 years (13,841 days).
Specimen MBCProject_0099_T3_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bd360c5-181d-416f-b10d-2c07e48eb502.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0099_SALIVA (Saliva), aliquot MBCProject_0099_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0da6e095-72ab-419c-9735-b78c282458a3

The open-access MAF lists 68 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 11, 3'UTR 4, Nonsense Mutation 3, Intron 3, Frame Shift Ins 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 189/335 reads (56%) | catalogued as rs201366610, CM930192, COSV63767999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs544043509; called by mutect2, varscan2
- ACOT11 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs201069943; called by muse, mutect2, varscan2
- ACTL7A | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs777158390, COSV100452976; called by muse, mutect2, varscan2
- ACVR1B | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460557299, COSV57776372, COSV57780549; called by muse, mutect2, varscan2
- APOB | c.7945G>T p.E2649* | Nonsense Mutation (SNP) | VAF 24/147 reads (16%) | catalogued as COSV51925442; called by muse, mutect2, varscan2
- BPHL | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs369891214; called by muse, mutect2
- CHRNA4 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as rs200666489; called by muse, mutect2, varscan2
- CYP27A1 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV51469691; called by muse, mutect2
- DDX18 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as rs1254497817; called by muse, mutect2
- DNAH9 | c.8875G>A p.G2959R | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52374475; called by muse, mutect2, varscan2
- EPHB6 | c.165+1dup | Frame Shift Ins (INS) | VAF 26/98 reads (27%) | catalogued as rs771807343; called by mutect2, varscan2
- GABRQ | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs1423609611; called by muse, mutect2, varscan2
- HHATL | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377213413; called by muse, mutect2, varscan2
- IK | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70258046; called by muse, mutect2
- KRT28 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 205/593 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs763555183, COSV60683964; called by muse, mutect2, varscan2
- NBEAL1 | c.2663G>A p.S888N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1167820719; called by muse, mutect2
- NDST1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs887501929; called by muse, mutect2, varscan2
- OTOP2 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748804126, COSV58880389; called by muse, mutect2, varscan2
- RAI14 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV99462814; called by muse, mutect2, varscan2
- ROS1 | c.4649G>T p.W1550L | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs561775569; called by muse, mutect2, varscan2
- SH3RF3 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs373580159; called by muse, mutect2, varscan2
- TCF21 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs551355616, COSV52818094; called by muse, mutect2, varscan2
- TENM4 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.166); catalogued as rs972268579; called by muse, mutect2
- TST | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs768409198; called by muse, mutect2, varscan2
- ZBTB10 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); catalogued as COSV66948489, COSV99061174; called by muse, mutect2, varscan2
- ZNF74 | c.35-5G>A | Splice Region (SNP) | VAF 8/37 reads (22%) | catalogued as rs1371773287; called by muse, mutect2, varscan2
- ATP1A3 | c.2477C>T p.A826V (on ENST00000545399 / NM_001256214.2; = p.A813V on NM_152296.5) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CFAP45 | c.8T>G p.L3R | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CSMD1 | c.7205T>C p.F2402S (on ENST00000520002; = p.F2401S on NM_033225.6) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- CXADR | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DTNA | c.1245G>T p.M415I | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EGFR | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- EMSY | c.798_802dup p.T268Nfs*15 | Frame Shift Ins (INS) | VAF 20/210 reads (10%) | called by mutect2, pindel
- FAM200B | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- GDF6 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 124/492 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GDF6 | c.508C>A p.R170S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- GGA1 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- GTPBP3 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- MAP3K14 | c.1587C>A p.H529Q | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, varscan2
- MEGF9 | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 126/194 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MSL1 | c.892G>A p.E298K (on ENST00000398532 / NM_001365919.1; = p.E35K on NM_001012241.2) | Missense Mutation (SNP) | VAF 122/1466 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); called by muse, mutect2
- OR10Z1 | c.746T>C p.I249T | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4D6 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- SCAF1 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); called by muse, mutect2
- SIRPA | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- TOP2A | c.3890C>T p.S1297L | Missense Mutation (SNP) | VAF 60/598 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.273); called by muse, mutect2
- USP27X | c.1041G>T p.M347I | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- WTAP | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- APOB | c.3264G>A p.T1088= | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as rs773824710; called by muse, mutect2, varscan2
- BCAT2 | c.1128G>T p.L376= | Silent (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- CHST3 | c.711C>T p.F237= | Silent (SNP) | VAF 39/180 reads (22%) | catalogued as rs1050116997; called by muse, mutect2, varscan2
- CSK | c.780C>T p.G260= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs930375989; called by muse, mutect2, varscan2
- IGSF11 | c.42C>T p.L14= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs778886399; called by muse, mutect2, varscan2
- MYOZ1 | c.165G>A p.R55= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- SCAMP5 | c.219C>T p.L73= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs780031176; called by muse, mutect2, varscan2
- TPBGL | c.900C>T p.A300= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- UBN2 | c.3111A>T p.P1037= | Silent (SNP) | VAF 51/207 reads (25%) | called by muse, mutect2, varscan2
- XKR9 | c.141T>C p.F47= | Silent (SNP) | VAF 53/503 reads (11%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.378G>A p.P126= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs200371392; called by muse, mutect2, varscan2
- C2orf80 | c.-76+20G>A | Intron (SNP) | VAF 44/226 reads (19%) | catalogued as rs1559346920; called by muse, mutect2, varscan2
- CRTC3 | c.476+16C>T | Intron (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.*19C>T | 3'UTR (SNP) | VAF 19/210 reads (9%) | called by muse, mutect2
- LITAF | c.*125C>G | 3'UTR (SNP) | VAF 66/455 reads (15%) | called by muse, mutect2, varscan2
- PARVG | c.*35C>G | 3'UTR (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- SRPK1 | c.13+49G>A | Intron (SNP) | VAF 15/67 reads (22%) | catalogued as COSV60411923; called by muse, mutect2, varscan2
- TBX20 | c.-48G>A | 5'UTR (SNP) | VAF 11/36 reads (31%) | catalogued as rs770883766; called by muse, mutect2, varscan2
- ZNF772 | c.*1086G>A | 3'UTR (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
